Gene-level copy-number profile of tumor specimen TCGA-SR-A6MX-05A from TCGA case TCGA-SR-A6MX, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Paraganglioma, malignant; Tissue or organ of origin: Nervous system, NOS; Age at diagnosis: 55.3 years (20,186 days).
Specimen TCGA-SR-A6MX-05A: Sample type: Additional - New Primary; Tissue type: Tumor; Tumor descriptor: New Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PCPG.6cbb54d6-04b1-4ae4-b1d1-c1653469d3bb.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-SR-A6MX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 360 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e2248557-fde7-40bc-8b32-e0e6ff4f72c6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 2,391; copy number 2: 10,697; copy number 3: 1,160; copy number 4: 45,141; copy number 5: 655; copy number 6: 188; copy number 7: 25; copy number 8: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-SR-A6MX-05A-11D-A35H-01): tumor purity 0.61, ploidy 3.59, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:5,776,165–5,783,355, 1 gene: OR52N5.
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.
- chr19:20,416,514–20,571,095, 3 genes (within-gene range 0–5): BNIP3P22, AC008554.1, BNIP3P23.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
